Somatic mutation profile of tumor specimen TCGA-EJ-8474-01A (aliquot TCGA-EJ-8474-01A-11D-2395-08) from TCGA case TCGA-EJ-8474, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 70.0 years (25,561 days).
Specimen TCGA-EJ-8474-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73f86e35-ffab-439a-bcfc-9fbf2dafaeeb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-8474-10A (Blood Derived Normal), aliquot TCGA-EJ-8474-10A-01D-2395-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97d8e99a-794c-445e-a84a-1db2f301fecb

The open-access MAF lists 46 somatic variants for this specimen: 29 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 16, Nonsense Mutation 2, Frame Shift Del 2, Frame Shift Ins 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1A | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1064794263, CM065992, COSV64194216, COSV64200368; ClinVar: likely pathogenic; called by muse, mutect2
- ADAM23 | c.1508C>T p.T503M | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs1459677969, COSV52231821; called by muse, mutect2, varscan2
- AHNAK2 | c.14364G>C p.E4788D | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV60932318; called by muse, mutect2, varscan2
- ANKRD27 | c.1184C>T p.S395L | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.553); catalogued as rs201398434, COSV60131683; called by muse, mutect2, varscan2
- ANXA11 | c.1402G>T p.D468Y | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55418856; called by muse, mutect2
- BEST4 | c.71G>A p.W24* | Nonsense Mutation (SNP) | VAF 26/252 reads (10%) | catalogued as rs1484659087, COSV64734566; called by muse, mutect2
- DPYSL5 | c.1660G>A p.A554T | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.941); catalogued as COSV56516725; called by muse, mutect2, varscan2
- FAM47C | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.133); catalogued as COSV63724527; called by muse, mutect2, varscan2
- HNRNPD | c.445G>T p.E149* | Nonsense Mutation (SNP) | VAF 14/114 reads (12%) | catalogued as COSV58315034; called by muse, mutect2, varscan2
- KANK4 | c.1579G>A p.D527N | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs777299965, COSV62989570; called by muse, mutect2, varscan2
- KIAA1549L | c.3046G>A p.V1016I (on ENST00000321505; = p.V1313I on NM_012194.3) | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.194); catalogued as rs765763365, COSV55775990; called by muse, mutect2
- MMP16 | c.602G>A p.G201E | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54191623; called by muse, mutect2, varscan2
- MROH2B | c.3875A>G p.E1292G | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.717); catalogued as COSV68190021; called by muse, mutect2, varscan2
- MUC15 | c.565G>A p.G189R | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV55557595; called by muse, mutect2
- MYH2 | c.3394C>T p.R1132W | Missense Mutation (SNP) | VAF 60/179 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs745807547, COSV55431734; called by muse, mutect2, varscan2
- NOVA2 | c.370A>T p.T124S | Missense Mutation (SNP) | VAF 64/219 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); catalogued as COSV54360208; called by muse, mutect2, varscan2
- OPN5 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 61/197 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as rs751407060, COSV55247797; called by muse, mutect2, varscan2
- OR2A14 | c.607G>A p.V203M | Missense Mutation (SNP) | VAF 46/416 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.18); catalogued as rs199919624, COSV68717969; called by muse, mutect2, varscan2
- PTPRU | c.3646G>T p.D1216Y | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60531130, COSV60537345; called by muse, mutect2, varscan2
- SHC1 | c.530G>A p.R177H (on ENST00000368445 / NM_183001.5; = p.R67H on NM_003029.5) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63535204; called by muse, mutect2, varscan2
- SPRR1A | c.141G>T p.E47D | Missense Mutation (SNP) | VAF 22/311 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV61081685; called by muse, mutect2
- THEMIS | c.1052C>T p.T351M | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200529297, COSV64069470; called by muse, mutect2, varscan2
- TMPRSS11F | c.436del p.I146Lfs*9 | Frame Shift Del (DEL) | VAF 20/61 reads (33%) | catalogued as rs774592951; called by mutect2, pindel, varscan2
- TNF | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs772270241, COSV69305263; called by muse, mutect2
- WWP1 | c.816T>G p.N272K | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV55364700; called by muse, mutect2, varscan2
- ZNF35 | c.670T>C p.C224R | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56077587; called by muse, mutect2
- EVI5 | c.2261del p.G754Vfs*69 | Frame Shift Del (DEL) | VAF 34/121 reads (28%) | called by mutect2, pindel, varscan2
- RNF213 | c.8578_8579insGCTC p.L2860Rfs*12 | Frame Shift Ins (INS) | VAF 8/49 reads (16%) | called by pindel, varscan2
- RNF213 | c.8579_8580insCG p.H2861Gfs*35 | Frame Shift Ins (INS) | VAF 20/53 reads (38%) | called by mutect2, varscan2*
- ABCC4 | c.576C>G p.G192= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV65318912; called by muse, mutect2, varscan2
- AKAP9 | c.4401A>G p.G1467= | Silent (SNP) | VAF 4/80 reads (5%) | catalogued as rs1215615118, COSV62341833; ClinVar: likely benign; called by muse, mutect2
- ARHGAP39 | c.1026C>T p.A342= | Silent (SNP) | VAF 7/75 reads (9%) | catalogued as rs780310869, COSV52776174, COSV99431700; called by muse, mutect2, varscan2
- CERK | c.933C>T p.Y311= | Silent (SNP) | VAF 18/159 reads (11%) | catalogued as rs377639952; called by muse, mutect2, varscan2
- DLST | c.1137G>A p.S379= | Silent (SNP) | VAF 9/139 reads (6%) | catalogued as rs764106634, COSV53168115; called by muse, mutect2
- EYS | c.936C>T p.S312= | Silent (SNP) | VAF 10/155 reads (6%) | catalogued as COSV61001241; called by muse, mutect2
- FCRL3 | c.885C>T p.T295= | Silent (SNP) | VAF 16/184 reads (9%) | catalogued as rs754929262, COSV63840429, COSV63843858; called by muse, mutect2
- FHOD1 | c.3096C>T p.P1032= | Silent (SNP) | VAF 58/169 reads (34%) | catalogued as COSV50760542; called by muse, mutect2, varscan2
- GGN | c.915T>C p.V305= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV53059209; called by muse, mutect2
- MYLK | c.660C>A p.I220= | Silent (SNP) | VAF 10/249 reads (4%) | catalogued as COSV60623781; called by muse, mutect2
- OR56A1 | c.696A>G p.K232= | Silent (SNP) | VAF 38/89 reads (43%) | catalogued as COSV57364020; called by muse, mutect2, varscan2
- OSR1 | c.195G>A p.P65= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as rs1248800793, COSV55345569; called by muse, mutect2
- PCDH11Y | c.552G>A p.S184= (on ENST00000400457 / NM_032973.2; = p.S173= on NM_032971.3) | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as COSV53092766; called by muse, mutect2
- SEC14L5 | c.258G>A p.L86= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as COSV52042412; called by muse, mutect2, varscan2
- TG | c.4176C>T p.G1392= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as COSV55096067; called by muse, mutect2, varscan2
- UVSSA | c.1131A>G p.K377= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV66231062; called by muse, mutect2, varscan2
- CHD6 | c.-23-12694C>T | Intron (SNP) | VAF 10/41 reads (24%) | catalogued as rs780152773, COSV58562840; called by muse, mutect2, varscan2
